Surgical pathology report (de-identified scan), TCGA case TCGA-HC-A4ZV, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-HC-A4ZV-01A (Primary Tumor).

[page 1 of 4]
Patient Results

M

Path Report

Final

Final

SURGICAL PATHOLOGY REPORT

ACCESSION NO. [REDACTED]

Final Diagnosis(es):

- (A) Lymph node, left obturator, excision: Five lymph nodes negative for metastasis (0/5).
- (B) Lymph node, right obturator, excision: Eight lymph nodes negative for metastasis (0/8).
- (C) Right apical margin, excision:
- 1) Lymphoid and adipose tissue.
- 2) Negative for malignancy.
- (D) Left apical margin, excision:
- 1) Fibrofatty tissue and skeletal muscle with hemorrhage.
- 2) No malignancy identified.
- (E) Prostate and seminal vesicles, radical prostatectomy:
- 1) Prostatic adenocarcinoma.
- 2) Gleason sum score 5+4=9/10.
- 3) Greater than 90% of prostate involved. Est volume 5x3x3=45cc
- 4) Extensive extraprostatic extension.
- 5) Bilateral seminal vesicle involvement.
- 6) Multiple surgical margins positive (see synoptic report).
- 7) Pathologic stage: pT3bNoMx
- (F) Posterior apical margin, excision:
- Positive for prostatic adenocarcinoma, Gleason sum score 5+5=9/10.
- (G) Right seminal vesicles, excision:
- 1) Prostatic adenocarcinoma, Gleason sum score 5+4=9/10.
- 2) Fibrovascular tissue and nerve ganglia.
- 3) No seminal vesicle identified.
- (H) left bladder neck margin, excision:
- 1) Fibromuscular tissue with chronic inflammation.
- 2) No tumor identified.

Synoptic Report:

Diagnosis: Prostatic adenocarcinoma
Procedure: Radical prostatectomy
Specimen Size: 5.5 x 5.0 x 5.0 cm
Specimen Weight: 65 gm
Lymph Node Sampling: Pelvic lymph node dissection
Histologic Type: Adenocarcinoma, acinar type
Histologic Grade (Gleason pattern)
Primary Pattern: Grade 5
Secondary Pattern: Grade 4
Total Gleason Score: 9
Tertiary Histologic Grade: Not applicable
Percent of Prostate Involved: >90%
Size of Dominant Nodule
Greatest dimension: 50 mm
Extraprostatic Extension: Extensive

ICD-0-3

adenocarcinoma, acinar 8550/3
Site: prostate, NOS C61.9

fw
11/4/12

[page 2 of 4]
Patient Results

M

Seminal Vesicle Invasion:

Left: Positive

Right: Positive

Lymph-vascular Invasion: Negative

Perineural Invasion: Positive

Margins:

Apical: Positive (part F), posterior

Bladder neck: Positive

Anterior: Negative

Lateral: Positive, right

Posterolateral: Positive, bilateral

Posterior: Positive

Nodes: Node Group: Left obturator

Total: 5

Positive: 0

Node Group: Right obturator

Total: 8

Positive: 0

Pathologic Stage: pT3b pN0 Mx

M.D.

Specimen(s) Received:

A: Left obturator LN

B: Right obturator LN

C: Right apical margin

D: Left apical margin

E: Prostate and seminal vesicles

F: Posterior apical margin

G: Right seminal vesicle

H: Left bladder neck margin

Clinical History:

Prostate cancer.

Intraoperative Consultation:

Time Received:

Time Reported:

FSC1: Right apical margin: Fibrotic fatty tissue, muscle, lymphoid tissue, negative for cancer (1 block).

FSD1: Left apical margin: Fibrotic fatty tissue, muscle, lymphoid tissue, negative for cancer (1 block).

MD

MD (Resident)

Gross Description:

(A) (left obturator lymph node) Received in formalin is multiple fragmented tissue pieces with an aggregate measurement of 3.5 x 3.9 x 1.8 cm. The tissue is tan to red, fibroadipose tissue. Six presumptive nodes are found varying in length from 2.2 to 2.5 cm. One node is submitted in cassettes A1-A5.

Printed from: Default

Page: 2 of 5

[page 3 of 4]
[REDACTED]

Patient Results

[REDACTED] M

(B) (right obturator lymph node) Received in formalin is a mass of tissue measuring 6.5 x 3.5 x 2.2 cm. The tissue is red to tan and fibrofatty. Seven lymph nodes ranging from 1.1 cm to 5.2 cm are identified. Lymph nodes are submitted within block B1. One bisected node within block B2, one node in B3, one bisected node within B4, the largest node is cut in half, bisected and submitted in B5 and B6.

(C) (right apical margin) Received fresh for frozen section is red-brown tissue which is unoriented that is 1.4 x 0.5 x 0.4 cm and submitted entirely in FSC1.

(D) (left apical margin) Received fresh for frozen section is red-brown tissue which is unoriented that is 1.0 x 1.5 x 0.2 cm and submitted entirely in FSD1.

(D) (prostate and seminal vesicles) Received in formalin is a radical prostatectomy which measures 5.0 cm superior to inferior, 5.5 cm anterior to posterior and 5.0 cm from right to left. The prostate is tightly adherent to the seminal vesicles and weighs 65 gm. The right part of the specimen is inked red, the left inked green and the posterior stripe is inked black.

Upon sectioning there is marked periurethral nodularity comprising approximately 80% of the specimen. There is also a punctate hemorrhage in the posterior base bilaterally. The apex is radially sectioned from right to left and submitted in order from E1 to E5. Blocks E6-E40 are submitted corresponding to the diagram which is attached to the paperwork. The seminal vesicles which were oriented right and left are submitted in blocks E42-E48 and unoriented and nonspecific seminal vesicle is submitted in blocks E49-E52 according to the diagram.

(F) (posterior apical margin) Received in formalin are two tissue fragments varying in color from purple to tan-pink with greatest measurement of 1.0 cm, both are submitted in cassette F1 entirely.

(G) (right seminal vesicles) Received in formalin is a strip of tissue measuring 3.0 x 1.2 x 0.7 cm. The tissue varies from tan to red-purple. The specimen is serially sectioned and submitted in cassette G1.

(H) (left bladder neck margin) Received in formalin is a strip of tissue which measures 2.0 and has widths varying from 0.5 to 0.2 cm. The specimen ranges in color from tan-brown to purple-black and is submitted entirely in H1. [REDACTED]

Microscopic Description:

Complete microscopic evaluation has been performed. [REDACTED]

Appropriately reacting controls have been performed and evaluated for all stains on this case as required.

Histopathology has a list of IH antibodies that are regulated as analyte specific reagents (ASR's). These assays were developed and their performance characteristics determined by the Histopathology Laboratory in the Department of Pathology at The [REDACTED] They

[page 4 of 4]
Patient Results

M

have not been cleared by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary for the ASR's. These tests are not investigational and are used in standard clinical care. In cases where Immunohistochemistry testing is performed, the following antibodies and their respective clones may be used to determine therapy for the patient: EFGR(31G7), ER(SP1), PR(1E2), Her2neu(4B5), CD117(Poly), CD20(L26). Unless otherwise stated in the report, all tissue tested for ERPR by IHC, Her2 by IHC and/or HER2 by FISH have been fixed as per ANP.22998 for a minimum of 6 hours and a maximum of 48 hours.

ER, PR, Ki-67, p53 are reported as a semi-quantitative percentage of positively stained nuclei. Her-2/neu and EGFR are scored as follows: No staining at all is scored as (0), weak, incomplete membrane staining in any proportion of cells is scored as (1+), less than strong but complete staining in any proportion of cells or complete strong staining in less than 30% of cells is scored as (2+), and strong complete staining in more than 30% of cells is scored as (3+). All studies are performed on tissue fixed in 10% neutral buffered formalin and embedded in paraffin unless otherwise stated in the report.

Review: [Signature]	Reviewed: 11/2/12	[Signature]

Printed from: Default

Source: NCI Genomic Data Commons file ee60bd19-30cd-431d-a728-559b8458f43f (TCGA-HC-A4ZV.424EBA82-F32C-4387-B919-F7C8F1212232.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).